Somatic mutation profile of tumor specimen TCGA-HQ-A5ND-01A (aliquot TCGA-HQ-A5ND-01A-11D-A26M-08) from TCGA case TCGA-HQ-A5ND, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 78.2 years (28,555 days).
Specimen TCGA-HQ-A5ND-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58edea5b-5950-4d02-a1d0-4c9efbacda8a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HQ-A5ND-10A (Blood Derived Normal), aliquot TCGA-HQ-A5ND-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f5b02649-951d-4fb6-82a2-5830a64d59f3

The open-access MAF lists 105 somatic variants for this specimen: 78 protein-altering or splice-affecting, 25 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 25, Nonsense Mutation 8, Splice Region 4, Frame Shift Ins 3, Frame Shift Del 3, 3'UTR 1, Splice Site 1, RNA 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.12688C>T p.Q4230* | Nonsense Mutation (SNP) | VAF 17/32 reads (53%) | catalogued as rs793888511, CM114913, COSV99978500; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABI3BP | c.2631G>T p.K877N | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as COSV52529875; called by muse, mutect2
- AC136428.1 | c.341A>G p.Y114C | Missense Mutation (SNP) | VAF 58/231 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs762831437, COSV71169072; called by muse, mutect2, varscan2
- ADAM30 | c.1822G>T p.D608Y | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65560496, COSV65561454; called by muse, mutect2, varscan2
- ANXA8 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.996); catalogued as rs1363433818; called by muse, mutect2, varscan2
- AP002512.3 | c.55C>T p.R19* | Nonsense Mutation (SNP) | VAF 5/45 reads (11%) | catalogued as rs1461011219, COSV56567313; called by muse, mutect2, varscan2
- APC | c.3883G>A p.E1295K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as COSV57323670, COSV57328904, COSV57399512; called by muse, mutect2, varscan2
- ATG4C | c.264G>A p.W88* | Nonsense Mutation (SNP) | VAF 4/29 reads (14%) | catalogued as COSV100507919; called by muse, mutect2, varscan2
- BHLHE41 | c.373C>T p.Q125* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as COSV54378814; called by muse, mutect2, varscan2
- C7orf31 | c.868C>T p.P290S | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as COSV52216285; called by muse, mutect2
- CALD1 | c.317G>C p.R106T | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62645635; called by muse, mutect2, varscan2
- CDH16 | c.2446C>T p.P816S | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as COSV55335215; called by muse, mutect2, varscan2
- CFTR | c.2163G>A p.M721I | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV50042603; called by muse, mutect2, varscan2
- CLTC | c.994G>T p.E332* | Nonsense Mutation (SNP) | VAF 10/96 reads (10%) | catalogued as COSV99291865; called by muse, mutect2
- COL4A5 | c.894T>C p.G298= | Splice Region (SNP) | VAF 33/44 reads (75%) | catalogued as COSV60357266; called by muse, mutect2, varscan2
- CTNNA2 | c.1381C>A p.Q461K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV58138714; called by muse, mutect2, varscan2
- DAAM2 | c.392A>C p.E131A | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51303859; called by muse, mutect2
- DAGLA | c.1371G>A p.L457= | Splice Region (SNP) | VAF 12/65 reads (18%) | catalogued as COSV57194569; called by muse, mutect2, varscan2
- DBNL | c.861G>C p.Q287H (on ENST00000448521 / NM_001014436.3; = p.Q288H on NM_014063.7) | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV51977270; called by muse, mutect2, varscan2
- DCP1B | c.313G>T p.A105S | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV54967649; called by muse, mutect2, varscan2
- DCTN2 | c.221G>C p.G74A (on ENST00000548249 / NM_001261413.2; = p.G79A on NM_006400.4) | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.253); catalogued as COSV71552949; called by muse, mutect2, varscan2
- DNAH17 | c.4739G>A p.R1580Q | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778930339, COSV67750474; called by muse, mutect2
- DNAH2 | c.5329G>A p.V1777I | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs577925267, COSV66717265; called by muse, mutect2, varscan2
- DNAH5 | c.2479C>T p.R827C | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760986984, COSV54208607; called by muse, mutect2
- ELAVL3 | c.391G>T p.G131W | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63645287; called by muse, mutect2, varscan2
- EPHA5 | c.1361C>T p.A454V | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV56634096, COSV56642914; called by muse, mutect2, varscan2
- ESF1 | c.1996G>C p.D666H | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52519446; called by muse, mutect2, varscan2
- FLG2 | c.6004G>A p.A2002T | Missense Mutation (SNP) | VAF 67/355 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV66167059; called by muse, mutect2, varscan2
- GPR162 | c.1118G>A p.G373E (on ENST00000311268 / NM_019858.2; = p.G89E on NM_014449.2) | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.998); catalogued as COSV51831367; called by muse, mutect2, varscan2
- H2AC20 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV58611399, COSV58611757; called by muse, mutect2, varscan2
- HEATR4 | c.2267T>G p.L756R | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58570325; called by muse, mutect2, varscan2
- IQUB | c.485C>T p.S162L | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs758626615, COSV61237624; called by muse, mutect2, varscan2
- KCNC1 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.475); catalogued as COSV56392156; called by muse, mutect2, varscan2
- KDM4A | c.202C>G p.P68A | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as COSV64958940; called by muse, mutect2, varscan2
- KLK15 | c.85G>T p.A29S | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0.026); catalogued as rs1203441608, COSV56826139; called by muse, mutect2, varscan2
- LAMP5 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs761575388, COSV55715297; called by muse, mutect2, varscan2
- MED17 | c.1240G>C p.D414H | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.58); catalogued as COSV52599743; called by muse, mutect2, varscan2
- MLYCD | c.934G>A p.V312I | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.209); catalogued as rs781754033, COSV52304225; called by muse, mutect2, varscan2
- MPIG6B | c.334C>A p.H112N | Missense Mutation (SNP) | VAF 77/162 reads (48%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV65389396; called by muse, mutect2, varscan2
- MPRIP | c.2758A>G p.I920V | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.519); catalogued as COSV57925817; called by muse, mutect2, varscan2
- MUC7 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 55/249 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.056); catalogued as COSV59217327; called by muse, mutect2, varscan2
- NOX5 | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV52985687; called by muse, mutect2, varscan2
- NPC1L1 | c.3715-1G>A p.X1239_splice | Splice Site (SNP) | VAF 9/27 reads (33%) | catalogued as COSV56922978; called by muse, mutect2
- NRCAM | c.2635C>T p.Q879* (on ENST00000379028 / NM_001371124.1; = p.Q863* on NM_005010.4 and 21 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 8/15 reads (53%) | catalogued as COSV100694375; called by muse, mutect2, varscan2
- OR2T33 | c.352T>C p.Y118H | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100531703; called by muse, mutect2
- PARP4 | c.988C>T p.H330Y | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs1449117023, COSV67960838; called by muse, mutect2, varscan2
- PARP8 | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | catalogued as COSV99890352; called by muse, mutect2, varscan2
- PIGA | c.955G>T p.V319L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.202); catalogued as rs765961204, COSV61237107; called by mutect2, varscan2
- PIK3C3 | c.673A>G p.K225E | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV56276567; called by muse, mutect2, varscan2
- PKD1 | c.11429C>A p.S3810Y (on ENST00000262304 / NM_001009944.3; = p.S3809Y on NM_000296.4) | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51911880; called by muse, mutect2, varscan2
- PSG3 | c.573C>A p.H191Q | Missense Mutation (SNP) | VAF 27/352 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.014); catalogued as COSV59502868; called by muse, mutect2
- PSPN | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 10/40 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.827); catalogued as COSV55531862; called by muse, mutect2, varscan2
- PTK6 | c.671A>G p.D224G | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.99); PolyPhen benign (0.007); catalogued as COSV53916061; called by muse, mutect2, varscan2
- RHOB | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as COSV55355253; called by muse, mutect2, varscan2
- RYR3 | c.1876C>T p.R626W | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs760906719, COSV66780293, COSV66811073; called by muse, mutect2, varscan2
- SLFN5 | c.1526C>T p.S509L | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs755184137, COSV55479960; called by muse, mutect2, varscan2
- SPANXN3 | c.78G>A p.E26= | Splice Region (SNP) | VAF 37/49 reads (76%) | catalogued as rs1341491026, COSV65140051, COSV65140291; called by muse, varscan2
- STAB2 | c.6686C>T p.T2229I | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66335415; called by muse, mutect2, varscan2
- STAR | c.91A>G p.I31V | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.075); catalogued as COSV52416974; called by muse, mutect2, varscan2
- SUZ12 | c.2078C>T p.S693F | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.205); catalogued as COSV59498403; called by muse, varscan2
- TECPR1 | c.3019G>A p.G1007S | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs751286336, COSV65782740; called by muse, mutect2, varscan2
- TMCO4 | c.835A>G p.I279V | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV53869772; called by muse, mutect2, varscan2
- TRIP13 | c.1295T>A p.I432N | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV51319342; called by muse, mutect2, varscan2
- TTLL3 | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs772431227, COSV59613657; called by muse, mutect2, varscan2
- TTN | c.11572C>G p.Q3858E (on ENST00000591111; = p.Q3812E on NM_003319.4) | Missense Mutation (SNP) | VAF 30/40 reads (75%) | catalogued as COSV59917575; called by muse, mutect2, varscan2
- UMOD | c.1517G>A p.C506Y | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV56774089; called by muse, mutect2, varscan2
- ZFHX3 | c.7576C>T p.Q2526* | Nonsense Mutation (SNP) | VAF 16/116 reads (14%) | catalogued as COSV51734237; called by muse, mutect2, varscan2
- ZNF521 | c.2022_2023insT p.N675* | Frame Shift Ins (INS) | VAF 21/126 reads (17%) | catalogued as COSV64123293; called by mutect2, pindel, varscan2
- ZNF566 | c.535A>G p.T179A | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV67573288; called by muse, mutect2
- ZNF595 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs1054039375, COSV59547738; called by muse, mutect2, varscan2
- AMFR | c.513+2_513+3insAT | Splice Region (INS) | VAF 18/103 reads (17%) | called by mutect2, pindel, varscan2
- CEP57L1 | c.690A>G p.I230M | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2
- EPC2 | c.207dup p.E70Rfs*9 | Frame Shift Ins (INS) | VAF 12/42 reads (29%) | called by mutect2, varscan2
- KMT2C | c.643_646del p.T215Lfs*45 | Frame Shift Del (DEL) | VAF 20/68 reads (29%) | called by mutect2, pindel, varscan2
- RIC1 | c.4130_4131dup p.R1378Afs*60 | Frame Shift Ins (INS) | VAF 29/65 reads (45%) | called by mutect2, pindel, varscan2
- SEMA4G | c.2365_2395del p.R789* (on ENST00000370250; = p.R794* on NM_017893.3) | Frame Shift Del (DEL) | VAF 13/78 reads (17%) | called by mutect2, pindel, varscan2
- TP53 | c.64del p.L22Yfs*22 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | called by mutect2, pindel, varscan2
- TRAV3 | c.124T>C p.C42R | Missense Mutation (SNP) | VAF 42/59 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- ARF3 | c.531C>T p.L177= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV99873033; called by mutect2, varscan2
- ARSI | c.222G>T p.L74= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV60816828; called by muse, mutect2, varscan2
- AVPR2 | c.672C>T p.C224= | Silent (SNP) | VAF 83/97 reads (86%) | catalogued as COSV100509424, COSV61685881; called by muse, mutect2, varscan2
- CARD11 | c.2934C>T p.L978= | Silent (SNP) | VAF 18/116 reads (16%) | catalogued as COSV67797428; called by muse, mutect2, varscan2
- CNGA3 | c.285G>A p.P95= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as rs1469543969, COSV55622810; called by muse, mutect2, varscan2
- CST9L | c.255T>C p.T85= | Silent (SNP) | VAF 21/99 reads (21%) | catalogued as rs1474283401, COSV100980817, COSV65407617; called by muse, mutect2, varscan2
- DVL2 | c.669C>T p.S223= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as COSV50034846; called by muse, mutect2, varscan2
- EIF4H | c.654C>T p.V218= | Silent (SNP) | VAF 9/94 reads (10%) | catalogued as rs138158412; called by muse, mutect2
- IGSF1 | c.2514G>A p.S838= | Silent (SNP) | VAF 68/305 reads (22%) | catalogued as rs763692298, COSV63836453, COSV63839322; called by muse, mutect2, varscan2
- JRKL | c.291A>T p.I97= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV53592412, COSV53593370; called by muse, mutect2, varscan2
- MAMDC4 | c.783C>T p.N261= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV56031975; called by muse, mutect2
- NSMAF | c.990C>G p.L330= | Silent (SNP) | VAF 24/164 reads (15%) | catalogued as COSV50684157, COSV99232658; called by muse, mutect2, varscan2
- NUTM2F | c.186C>G p.T62= | Silent (SNP) | VAF 28/45 reads (62%) | catalogued as rs770291346, COSV53555722; called by muse, mutect2, varscan2
- OR6C2 | c.132C>T p.I44= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as rs367560540; called by muse, mutect2, varscan2
- PCLO | c.4350G>A p.E1450= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV61619925; called by muse, mutect2, varscan2
- PKD1 | c.11985C>G p.L3995= (on ENST00000262304 / NM_001009944.3; = p.L3994= on NM_000296.4) | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV51911872; called by muse, mutect2, varscan2
- RNGTT | c.1383T>C p.P461= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV55647006; called by muse, varscan2
- ROPN1B | c.474C>T p.F158= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as rs760854872, COSV52541770; called by muse, mutect2, varscan2
- SFXN3 | c.915G>C p.L305= | Silent (SNP) | VAF 39/116 reads (34%) | catalogued as COSV56519186; called by muse, mutect2, varscan2
- SLC9A8 | c.1335G>T p.R445= | Silent (SNP) | VAF 32/85 reads (38%) | catalogued as COSV64287381; called by muse, mutect2, varscan2
- STK10 | c.54A>G p.R18= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV51571089, COSV51579363; called by muse, mutect2, varscan2
- TAF2 | c.1041C>T p.A347= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV65417013; called by muse, mutect2, varscan2
- TPP2 | c.420T>C p.P140= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV65751302; called by muse, mutect2, varscan2
- TTN | c.312C>T p.P104= | Silent (SNP) | VAF 34/50 reads (68%) | catalogued as COSV59917592; called by muse, mutect2, varscan2
- WIZ | c.5322A>G p.E1774= (on ENST00000673675 / NM_001371589.1; = p.E679= on NM_021241.3) | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as rs1360159596, COSV54605063; called by muse, mutect2, varscan2
- AL136982.4 | n.653C>T | RNA (SNP) | VAF 40/125 reads (32%) | catalogued as rs373223872; called by muse, mutect2, varscan2
- XIRP2 | c.*1423T>A | 3'UTR (SNP) | VAF 27/60 reads (45%) | catalogued as COSV54686278; called by muse, mutect2, varscan2
